Somatic mutation profile of tumor specimen MP2PRT-PARUSM-TMP1-A (aliquot MP2PRT-PARUSM-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PARUSM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.7 years (1,734 days).
Specimen MP2PRT-PARUSM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8bd53055-39d0-4f69-96c6-f4a8398ce30e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARUSM-NB1-B (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARUSM-NB1-B-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df4eec21-b347-4f63-b79f-05e9bbc76c2c

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 17, Silent 7, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4336C>T p.R1446C | Missense Mutation (SNP) | VAF 31/277 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398124146, COSV52113365, COSV52115600, COSV52116725; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 64/256 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 45/371 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APLNR | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 47/552 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.559); catalogued as rs761618705, COSV57241345, COSV57242988; called by muse, mutect2
- AQP12B | c.452C>T p.A151V (on ENST00000621682; = p.A163V on NM_001102467.2) | Missense Mutation (SNP) | VAF 42/424 reads (10%) | SIFT tolerated (0.83); PolyPhen benign (0.024); catalogued as rs757028242; called by muse, mutect2, varscan2
- CALCR | c.1120G>A p.V374I (on ENST00000649521 / NM_001164737.2; = p.V358I on NM_001742.4) | Missense Mutation (SNP) | VAF 139/308 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0.014); catalogued as rs375960623; called by muse, mutect2, varscan2
- DUOX2 | c.2396G>A p.R799Q | Missense Mutation (SNP) | VAF 254/568 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs762753633, COSV66534081, COSV66535400; called by muse, mutect2, varscan2
- FOXA1 | c.305C>T p.T102M | Missense Mutation (SNP) | VAF 149/1764 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV51645124; called by muse, mutect2
- HKDC1 | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 104/397 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs755672415; called by muse, mutect2, varscan2
- KIAA1671 | c.1415C>T p.P472L | Missense Mutation (SNP) | VAF 193/408 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs1487776668; called by muse, mutect2, varscan2
- LIMCH1 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 50/332 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs764998077; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 183/592 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RFX5 | c.1396C>T p.R466W | Missense Mutation (SNP) | VAF 45/387 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1557830458, COSV99303292; called by muse, mutect2, varscan2
- RNF25 | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 291/554 reads (53%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as rs761674789; called by muse, mutect2, varscan2
- SCN10A | c.3109G>A p.E1037K | Missense Mutation (SNP) | VAF 149/304 reads (49%) | SIFT tolerated (0.56); PolyPhen benign (0.039); catalogued as rs376815753; called by muse, mutect2, varscan2
- ATAD2 | c.3442_3443del p.K1148Dfs*41 | Frame Shift Del (DEL) | VAF 40/447 reads (9%) | called by mutect2, pindel
- COQ2 | c.911A>C p.Q304P | Missense Mutation (SNP) | VAF 34/242 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SVEP1 | c.1444G>A p.G482R | Missense Mutation (SNP) | VAF 32/224 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- DENND2C | c.1353C>T p.A451= (on ENST00000393274 / NM_001256404.2; = p.A394= on NM_198459.4) | Silent (SNP) | VAF 103/235 reads (44%) | catalogued as rs775225611, COSV101283993, COSV67922415; called by muse, mutect2, varscan2
- FAM13A | c.36A>G p.K12= | Silent (SNP) | VAF 39/216 reads (18%) | called by muse, mutect2, varscan2
- KRTAP21-2 | c.63C>T p.S21= | Silent (SNP) | VAF 202/742 reads (27%) | catalogued as rs781308785, COSV100441253, COSV61684214; called by muse, mutect2, varscan2
- PDZRN3 | c.162G>A p.A54= | Silent (SNP) | VAF 67/554 reads (12%) | catalogued as rs779129313; called by muse, mutect2, varscan2
- TBC1D3B | c.735G>A p.T245= | Silent (SNP) | VAF 177/1518 reads (12%) | catalogued as rs1402242475; called by muse, mutect2, varscan2
- TCEA3 | c.690G>A p.T230= | Silent (SNP) | VAF 58/345 reads (17%) | catalogued as rs752271585, COSV101508315; called by muse, mutect2, varscan2
- UNC80 | c.1035G>A p.E345= | Silent (SNP) | VAF 35/497 reads (7%) | called by muse, mutect2
